Gene-level copy-number profile of tumor specimen ALCH-B2T7-TTP1-A from ALCHEMIST case ALCH-B2T7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 62.1 years (22,700 days).
Specimen ALCH-B2T7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f2dc8bb-1bbd-4853-ad3e-f65dad8714a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2T7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/764ea76a-8038-4205-8fdd-e268d7107537

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 152; copy number 2: 58,220; copy number 3: 13; copy number 4: 4; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:13,949,095–13,949,666, 1 gene (within-gene range 0–2): MRPL35P1.
- chr12:123,721,246–123,721,639, 1 gene (within-gene range 0–2): RPL27P12.
- chr17:36,684,754–36,685,129, 1 gene: AC243830.3.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:57,828,331–57,837,046, 2 genes, copy number 7: AC023141.7, AC023141.13.

Autosomal genes at a single copy (total copy number 1): 152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
